TCGA case TCGA-DU-6401 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97cb8701-7d63-4142-b404-006fbb3ecb0b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Dead; Days to death: 2,660 days (7.3 years).

Diagnoses (2)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 31.7 years (11,595 days); Year of diagnosis: 1998; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 187 days; Days to treatment end: 228 days; Treatment dose: 5,400 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,903 days (5.2 years); Days to treatment end: 2,451 days (6.7 years); Number of cycles: 16; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Initial disease status: Progressive Disease; Days to treatment start: 2,512 days (6.9 years); Days to treatment end: 2,512 days (6.9 years); Number of cycles: 2; Treatment dose: 400 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Initial disease status: Progressive Disease; Days to treatment start: 2,542 days (7.0 years); Days to treatment end: 2,542 days (7.0 years); Number of cycles: 1; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Oligodendroglioma, NOS). Age at diagnosis: 36.9 years (13,481 days); Days to diagnosis: 1,886 days (5.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 2,464 days (6.7 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 1,886 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,886 days (5.2 years).
- Day 2,454 (preoperative): Karnofsky performance status: 100.
- Days to follow up: 2,660 days (7.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Vision Changes.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-6401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-DU-6401-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DU-6401-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DU-6401-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-6401-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Initial weight: 280 mg.
- Sample TCGA-DU-6401-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: Yes; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: > 181 Days; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Idh1 mutation test indicator: No.
- Drug treatment 1: Regimen number: 02; Pharmaceutical therapy drug name: Sorafenib (Bay 43-9006); Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 03; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 01; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,660 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,660 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,886 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-6401-01A-11D-1704-01): tumor purity 0.38, ploidy 1.87, whole-genome doublings 0.
